CCDI case PBBVNN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/c48f0de2-47fd-445e-b634-788d452e68ea

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Adrenal cortical adenoma, NOS: ICD-O-3 morphology code: 8370/0; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 2.5 years (914 days).

Biospecimens (2 samples)
- Sample 0DI7V3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DI7VL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
